Somatic mutation profile of tumor specimen C3L-01327-01 (aliquot CPT0064890009) from CPTAC case C3L-01327, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.4 years (27,160 days).
Specimen C3L-01327-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65517d18-4754-4037-a64b-7e89504ff851.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01327-31 (Blood Derived Normal), aliquot CPT0066690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cfc1fab-79db-46e7-8968-4700ebd680aa

The open-access MAF lists 101 somatic variants for this specimen: 68 protein-altering or splice-affecting, 26 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 26, 5'UTR 3, Frame Shift Del 3, Intron 3, Nonsense Mutation 3, Splice Site 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 171/387 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs373890183; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 3049/7000 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750439767, COSV100568353, COSV59198058; called by muse, mutect2, varscan2
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 76/176 reads (43%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- ARHGEF3 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745635085; called by muse, mutect2, varscan2
- BCL11A | c.1835del p.P612Rfs*144 (on ENST00000335712 / NM_001365609.1; = p.P646Rfs*132 on NM_018014.4) | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as COSV59636957; called by mutect2, pindel, varscan2
- BPIFC | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200041707, COSV53277973; called by muse, mutect2
- C5AR1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 100/375 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs774370669; called by muse, mutect2, varscan2
- CCDC9 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as rs761232596, COSV55721027; called by muse, mutect2, varscan2
- CDKL4 | c.1064T>C p.M355T | Missense Mutation (SNP) | VAF 113/365 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754569638; called by muse, mutect2, varscan2
- CLEC11A | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs1041981819; called by muse, mutect2, varscan2
- CNTN4 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs183942017, COSV61869453; called by muse, mutect2
- COL4A5 | c.3247G>C p.G1083R | Missense Mutation (SNP) | VAF 110/134 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM052215, COSV60373749; called by muse, mutect2, varscan2
- CRB2 | c.2912C>T p.S971L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs777713938; called by mutect2, varscan2
- CST8 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 85/367 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV55670938, COSV55671798; called by muse, mutect2, varscan2
- CYP4F2 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV99686244; called by muse, varscan2
- DOK2 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs546091332, COSV52388457; called by muse, mutect2, varscan2
- FGF1 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100532335; called by muse, mutect2, varscan2
- GPR174 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 67/83 reads (81%) | catalogued as rs1333054510, COSV52133979; called by muse, mutect2, varscan2
- IL6R | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs772744918; called by muse, mutect2, varscan2
- ISL1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 185/477 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs769362903, COSV57932054; called by muse, mutect2, varscan2
- KBTBD13 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101416682; called by muse, mutect2, varscan2
- LAMB1 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs760673566; called by muse, mutect2
- MCF2 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs766972582, COSV58483217; called by muse, mutect2
- MUC12 | c.7214C>A p.T2405N (on ENST00000379442; = p.T2262N on NM_001164462.1) | Missense Mutation (SNP) | VAF 71/1053 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); catalogued as rs1363938439; called by muse, mutect2
- MUC16 | c.12784A>G p.I4262V | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs776433382; called by muse, mutect2, varscan2
- NAP1L4 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs1203095682, COSV65880783; called by muse, mutect2, varscan2
- NEDD4L | c.1898G>A p.R633Q (on ENST00000400345 / NM_001144967.3; = p.R613Q on NM_015277.6) | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748722766, COSV56842924; called by muse, mutect2, varscan2
- NOTCH3 | c.6233G>A p.R2078Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as rs765403158, COSV54628708, COSV54639957; called by muse, mutect2, varscan2
- OR10G4 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 81/250 reads (32%) | catalogued as rs1342652966; called by muse, mutect2, varscan2
- PKP3 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.132); catalogued as rs760222882, COSV58989842; called by muse, mutect2, varscan2
- SIGLEC15 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as rs758328612, COSV104431363; called by muse, mutect2, varscan2
- SLIT2 | c.3583G>A p.G1195R | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs547207452; called by muse, mutect2, varscan2
- TAGAP | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57852160; called by muse, mutect2
- TBCK | c.2476G>A p.G826R (on ENST00000273980 / NM_001163436.4; = p.G763R on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV56755240, COSV99912537; called by muse, mutect2, varscan2
- TTI2 | c.693G>T p.W231C | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1279630432, COSV100659703; called by muse, mutect2, varscan2
- WSCD2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs371817011; called by muse, mutect2, varscan2
- ABCA4 | c.4562T>C p.I1521T | Missense Mutation (SNP) | VAF 169/478 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTL9 | c.657G>T p.E219D | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ADAMTS16 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGEF12 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BTG4 | c.504_507del p.Y169Rfs*5 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | called by mutect2, pindel, varscan2
- CRNN | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- DHRS11 | c.676-8G>A | Splice Region (SNP) | VAF 84/205 reads (41%) | called by muse, mutect2, varscan2
- DNAH9 | c.10764del p.A3589Lfs*13 | Frame Shift Del (DEL) | VAF 65/193 reads (34%) | called by mutect2, pindel, varscan2
- ELP3 | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- EXOC3L4 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FPR2 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, varscan2
- FSCB | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 26/329 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); called by muse, mutect2
- FZD7 | c.358T>C p.C120R | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIMAP5 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR148 | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by mutect2, varscan2
- HIVEP1 | c.7039G>A p.G2347R | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IMPG2 | c.1843C>G p.P615A | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IPO7 | c.906+1G>T p.X302_splice | Splice Site (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- KCNJ15 | c.627G>C p.Q209H | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- L3MBTL1 | c.1099G>A p.E367K (on ENST00000418998 / NM_001377303.1; = p.E277K on NM_015478.7) | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- LRP2 | c.10192C>A p.H3398N | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MTDH | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 103/258 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, varscan2
- MYRF | c.77C>A p.S26Y (on ENST00000278836 / NM_001127392.3; = p.S17Y on NM_013279.4) | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFATC4 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NR1H4 | c.1250C>G p.A417G (on ENST00000551379 / NM_001206993.2; = p.A403G on NM_005123.4) | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PARP8 | c.2090+1G>A p.X697_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 123/424 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRDM1 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PTPRC | c.3062C>G p.S1021C | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RUNX1 | c.838G>A p.A280T (on ENST00000344691 / NM_001001890.3; = p.A307T on NM_001754.5) | Missense Mutation (SNP) | VAF 206/436 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- STXBP2 | c.497C>A p.T166K | Missense Mutation (SNP) | VAF 128/450 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- AP2B1 | c.1638A>G p.P546= | Silent (SNP) | VAF 99/357 reads (28%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.69C>T p.C23= | Silent (SNP) | VAF 164/391 reads (42%) | catalogued as rs771333789, COSV59979171, COSV59983863; called by muse, mutect2, varscan2
- DCHS1 | c.4245G>A p.A1415= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- DHH | c.699G>A p.R233= | Silent (SNP) | VAF 91/195 reads (47%) | catalogued as rs752490740; called by muse, mutect2, varscan2
- EHD3 | c.408C>T p.F136= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as COSV100434786; called by muse, mutect2, varscan2
- FPR3 | c.117C>T p.F39= | Silent (SNP) | VAF 65/233 reads (28%) | catalogued as rs369595664; called by muse, mutect2, varscan2
- GCN1 | c.3528G>A p.R1176= | Silent (SNP) | VAF 120/347 reads (35%) | catalogued as COSV56112907; called by muse, mutect2, varscan2
- IGF1R | c.2460C>T p.F820= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as rs769964962, COSV51269910; called by muse, mutect2
- IL17A | c.234C>T p.R78= | Silent (SNP) | VAF 62/150 reads (41%) | called by muse, varscan2
- KCNS1 | c.891G>A p.T297= | Silent (SNP) | VAF 79/278 reads (28%) | catalogued as rs545216149, COSV100067075; called by muse, mutect2, varscan2
- LGSN | c.498A>G p.A166= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- LHX3 | c.630C>T p.A210= (on ENST00000371748 / NM_178138.6; = p.A215= on NM_014564.5) | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV65582969; called by muse, mutect2, varscan2
- LY75 | c.2634C>T p.S878= | Silent (SNP) | VAF 35/168 reads (21%) | catalogued as rs772853833, COSV55109379; called by muse, mutect2, varscan2
- MAG | c.1164A>T p.G388= | Silent (SNP) | VAF 146/532 reads (27%) | called by muse, mutect2, varscan2
- OR6C74 | c.612G>A p.T204= | Silent (SNP) | VAF 100/264 reads (38%) | catalogued as rs780093915; called by muse, mutect2, varscan2
- PIK3R2 | c.1719C>A p.I573= | Silent (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2
- RDX | c.1764G>C p.L588= | Silent (SNP) | VAF 84/245 reads (34%) | called by muse, mutect2, varscan2
- SCOC | c.30T>C p.D10= | Silent (SNP) | VAF 104/240 reads (43%) | catalogued as rs759629496; called by muse, mutect2, varscan2
- SGIP1 | c.756T>A p.P252= | Silent (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
- SLC5A11 | c.1971C>T p.D657= | Silent (SNP) | VAF 195/485 reads (40%) | catalogued as rs147778032; called by muse, mutect2, varscan2
- TFAP2D | c.168G>A p.A56= | Silent (SNP) | VAF 119/286 reads (42%) | catalogued as COSV50410479; called by muse, mutect2, varscan2
- TMPRSS3 | c.1179C>T p.G393= | Silent (SNP) | VAF 190/523 reads (36%) | catalogued as rs941433875, COSV52302752; called by muse, mutect2, varscan2
- TTLL1 | c.276G>A p.G92= | Silent (SNP) | VAF 22/356 reads (6%) | called by muse, mutect2
- UGT1A9 | c.492C>T p.P164= | Silent (SNP) | VAF 103/256 reads (40%) | called by muse, mutect2, varscan2
- URB1 | c.1452G>A p.V484= | Silent (SNP) | VAF 61/138 reads (44%) | called by muse, mutect2, varscan2
- ZC3H3 | c.69C>G p.T23= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as COSV52788676; called by muse, mutect2, varscan2
- BMS1P15 | n.610A>T | RNA (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- FLG | c.-10T>C | 5'UTR (SNP) | VAF 55/157 reads (35%) | called by muse, mutect2, varscan2
- GASK1B | c.910+54T>A | Intron (SNP) | VAF 85/274 reads (31%) | called by muse, mutect2, varscan2
- GATA6 | c.-16C>T | 5'UTR (SNP) | VAF 73/232 reads (31%) | called by muse, mutect2, varscan2
- GLT1D1 | c.-7C>T | 5'UTR (SNP) | VAF 16/29 reads (55%) | called by muse, varscan2
- PILRB | c.-217-88G>A | Intron (SNP) | VAF 88/258 reads (34%) | catalogued as rs544901633; called by muse, mutect2, varscan2
- SELENOW | c.54+34G>A | Intron (SNP) | VAF 52/250 reads (21%) | called by muse, mutect2, varscan2
